Somatic mutation profile of tumor specimen MMRF_2083_2_BM_CD138pos (aliquot MMRF_2083_2_BM_CD138pos_T1_KHS5U_L12851) from MMRF case MMRF_2083, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.8 years (24,404 days).
Specimen MMRF_2083_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c062004-6149-4261-bc17-66d66bf4c7b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2083_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2083_1_PB_Whole_C2_KHS5U_L08640; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea85eb8e-fc3d-4b3f-92df-bc6567572e80

The open-access MAF lists 89 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, 3'UTR 21, Silent 9, Intron 9, RNA 5, 5'Flank 5, 5'UTR 4, 3'Flank 2, Frame Shift Ins 2, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 39/94 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 115/135 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 54/126 reads (43%) | catalogued as rs767549806; called by mutect2, varscan2
- ANO4 | c.1713A>T p.K571N (on ENST00000392977 / NM_001286615.2; = p.K536N on NM_178826.4) | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54609704; called by muse, mutect2, varscan2
- ARHGEF28 | c.4397C>T p.A1466V | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs1269218553; called by muse, mutect2, varscan2
- CCNB3 | c.2275G>C p.V759L | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs782311092; called by muse, mutect2
- CCND1 | c.53C>G p.P18R | Missense Mutation (SNP) | VAF 109/227 reads (48%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV57122832; called by muse, mutect2, varscan2
- CFAP221 | c.1203del p.A402Hfs*7 | Frame Shift Del (DEL) | VAF 61/146 reads (42%) | catalogued as COSV54656906; called by mutect2, pindel, varscan2
- CSMD1 | c.9283G>T p.A3095S (on ENST00000520002; = p.A3094S on NM_033225.6) | Missense Mutation (SNP) | VAF 13/239 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV100152783, COSV59303561; called by muse, mutect2
- DACT2 | c.1746C>A p.S582R | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as COSV64694296; called by muse, mutect2, varscan2
- E2F7 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.395); catalogued as rs201812783, COSV59737248; called by muse, mutect2, varscan2
- FREM3 | c.3949G>C p.V1317L | Missense Mutation (SNP) | VAF 83/188 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV61682094; called by muse, mutect2, varscan2
- H2BC11 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 116/220 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV60361711; called by muse, mutect2, varscan2
- IGLV3-1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 133/229 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs754927085; called by muse, varscan2
- IGLV3-1 | c.110C>G p.A37G | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as rs529856363; called by muse, varscan2
- IGLV3-1 | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs143830449; called by muse, varscan2
- MPZ | c.530A>T p.Y177F | Missense Mutation (SNP) | VAF 115/251 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV60667609; called by muse, mutect2, varscan2
- NLRP2 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200257622, COSV99672225; called by muse, mutect2
- PNKP | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1187151464; called by muse, mutect2, varscan2
- RTTN | c.1932A>T p.E644D | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV55351992; called by muse, mutect2, varscan2
- SPTA1 | c.3119C>T p.P1040L | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as rs748522821, COSV63748200; called by muse, mutect2, varscan2
- TRIM55 | c.986-1G>C p.X329_splice | Splice Site (SNP) | VAF 26/51 reads (51%) | catalogued as COSV52547214; called by muse, mutect2, varscan2
- WDFY3 | c.6625C>T p.H2209Y | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.326); catalogued as COSV55712843; called by muse, mutect2, varscan2
- ADGRV1 | c.13433+2T>A p.X4478_splice | Splice Site (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- AKAP13 | c.7399A>G p.T2467A (on ENST00000394518 / NM_007200.5; = p.T2471A on NM_006738.6) | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM227B | c.374T>G p.L125R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IGHV1-69D | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.433); called by muse, varscan2
- KRT7 | c.994T>A p.L332M | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MROH9 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PLOD2 | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2
- SALL4 | c.680A>T p.Q227L | Missense Mutation (SNP) | VAF 11/305 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- SEL1L3 | c.2074C>T p.Q692* | Nonsense Mutation (SNP) | VAF 112/261 reads (43%) | called by muse, mutect2, varscan2
- SLC19A3 | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 18/372 reads (5%) | called by muse, mutect2
- TACR2 | c.1128_1129insA p.Q377Tfs*21 | Frame Shift Ins (INS) | VAF 144/293 reads (49%) | called by mutect2, pindel, varscan2
- APOB | c.10677A>C p.I3559= | Silent (SNP) | VAF 92/206 reads (45%) | called by muse, mutect2, varscan2
- CHRNA2 | c.48G>T p.L16= | Silent (SNP) | VAF 116/245 reads (47%) | called by muse, mutect2, varscan2
- ELOVL4 | c.54A>G p.A18= | Silent (SNP) | VAF 141/310 reads (45%) | catalogued as rs745792192; called by muse, mutect2, varscan2
- FMN2 | c.2172A>G p.E724= | Silent (SNP) | VAF 88/203 reads (43%) | catalogued as rs1414556146; called by muse, mutect2, varscan2
- HBD | c.274C>T p.L92= | Silent (SNP) | VAF 187/393 reads (48%) | catalogued as rs755850441; called by muse, mutect2, varscan2
- IGSF9 | c.2601C>T p.G867= (on ENST00000368094 / NM_001135050.2; = p.G851= on NM_020789.4) | Silent (SNP) | VAF 95/195 reads (49%) | called by muse, mutect2, varscan2
- PLCH2 | c.3753T>C p.A1251= | Silent (SNP) | VAF 184/398 reads (46%) | called by muse, mutect2, varscan2
- RHOBTB1 | c.1011G>A p.P337= | Silent (SNP) | VAF 142/345 reads (41%) | catalogued as rs768772830; called by muse, mutect2, varscan2
- TRO | c.4008C>A p.G1336= | Silent (SNP) | VAF 209/425 reads (49%) | called by muse, mutect2, varscan2
- ATP8A2 | c.*4311T>C | 3'UTR (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021153 G>C | 5'Flank (SNP) | VAF 148/291 reads (51%) | catalogued as rs1012416032, COSV55847562, COSV55847818; called by muse, mutect2, varscan2
- C5orf49 | c.*644T>C | 3'UTR (SNP) | VAF 14/317 reads (4%) | called by muse, mutect2
- CACNG8 | c.*989T>G | 3'UTR (SNP) | VAF 37/78 reads (47%) | called by muse, mutect2, varscan2
- CCDC140 | n.824A>G | RNA (SNP) | VAF 14/132 reads (11%) | called by mutect2, varscan2
- CDH19 | c.-105G>A | 5'UTR (SNP) | VAF 77/161 reads (48%) | called by muse, mutect2, varscan2
- CTSL3P | n.469C>T | RNA (SNP) | VAF 11/255 reads (4%) | called by muse, mutect2
- DCAF11 | c.*40A>C | 3'UTR (SNP) | VAF 28/406 reads (7%) | called by muse, mutect2
- DCHS2 | n.2616G>A | RNA (SNP) | VAF 51/117 reads (44%) | catalogued as rs760166424; called by muse, mutect2, varscan2
- DCK | c.*859A>G | 3'UTR (SNP) | VAF 85/196 reads (43%) | called by muse, mutect2, varscan2
- DDX27 | c.1367-47A>G | Intron (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- DNAJC19 | chr3:180989790 G>A | 5'Flank (SNP) | VAF 91/191 reads (48%) | called by muse, mutect2, varscan2
- DOK6 | c.-85G>A | 5'UTR (SNP) | VAF 25/59 reads (42%) | catalogued as rs574893333; called by muse, mutect2, varscan2
- EEF1A1 | chr6:73521102 C>A | 5'Flank (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2
- EGLN3 | c.*560A>C | 3'UTR (SNP) | VAF 42/79 reads (53%) | called by muse, mutect2, varscan2
- FAM133A | c.*967T>G | 3'UTR (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- GABRA1 | chr5:161898959 A>T | 3'Flank (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2
- GRIK2 | c.-192C>T | 5'UTR (SNP) | VAF 13/291 reads (4%) | called by muse, mutect2
- HABP2 | c.*213A>C | 3'UTR (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- HNRNPA2B1 | c.43-30T>C | Intron (SNP) | VAF 58/99 reads (59%) | catalogued as rs1444866150; called by muse, mutect2, varscan2
- HYDIN2 | n.4378G>A | RNA (SNP) | VAF 21/40 reads (53%) | catalogued as rs1187542740; called by muse, mutect2, varscan2
- INHBA | c.*1503A>G | 3'UTR (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- ITGB1BP2 | c.816+98G>A | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- KCTD21 | c.*1342G>A | 3'UTR (SNP) | VAF 79/155 reads (51%) | called by muse, mutect2, varscan2
- MALSU1 | chr7:23299108 A>T | 5'Flank (SNP) | VAF 79/165 reads (48%) | catalogued as rs912526663; called by muse, mutect2, varscan2
- MAP3K9 | c.*266C>G | 3'UTR (SNP) | VAF 64/128 reads (50%) | called by muse, mutect2, varscan2
- MAPK13 | c.-12C>T | 5'UTR (SNP) | VAF 62/155 reads (40%) | called by muse, mutect2, varscan2
- MCF2 | c.*258T>G | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- MMP14 | c.108+306T>G | Intron (SNP) | VAF 126/264 reads (48%) | catalogued as rs1323491827; called by muse, varscan2
- MTAP | c.813+2643G>A | Intron (SNP) | VAF 28/710 reads (4%) | called by muse, mutect2
- NEXMIF | c.*679A>C | 3'UTR (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- NXPH4 | c.*466C>T | 3'UTR (SNP) | VAF 262/543 reads (48%) | called by muse, mutect2, varscan2
- PDLIM5 | c.*3724dup | 3'UTR (INS) | VAF 65/146 reads (45%) | called by mutect2, pindel, varscan2
- PLEKHH1 | c.3285-11C>G | Intron (SNP) | VAF 198/512 reads (39%) | called by muse, mutect2, varscan2
- PLOD2 | c.1501-891C>A | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, varscan2
- PRECSIT | n.458dup | RNA (INS) | VAF 100/143 reads (70%) | catalogued as rs1178014204; called by mutect2, pindel, varscan2
- PROS1 | c.*941T>A | 3'UTR (SNP) | VAF 16/343 reads (5%) | called by muse, mutect2
- PWWP3A | chr19:1356333 G>A | 5'Flank (SNP) | VAF 59/123 reads (48%) | called by muse, mutect2, varscan2
- RNASEL | c.*123G>A | 3'UTR (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- RSPH9 | c.*492C>T | 3'UTR (SNP) | VAF 130/251 reads (52%) | called by muse, mutect2, varscan2
- SERTAD2 | c.*2711G>T | 3'UTR (SNP) | VAF 55/137 reads (40%) | called by muse, mutect2, varscan2
- SLC2A3 | c.1069-86G>A | Intron (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- TCERG1 | c.2910+69T>C | Intron (SNP) | VAF 16/30 reads (53%) | catalogued as rs1189389152; called by muse, mutect2
- TGFA | c.*24C>T | 3'UTR (SNP) | VAF 118/248 reads (48%) | catalogued as rs782252830; called by muse, mutect2, varscan2
- VANGL1 | chr1:115696558 A>T | 3'Flank (SNP) | VAF 52/100 reads (52%) | called by muse, mutect2, varscan2
- ZNF764 | c.*1331A>G | 3'UTR (SNP) | VAF 65/165 reads (39%) | catalogued as rs901665425; called by muse, mutect2, varscan2
